Somatic mutation profile of tumor specimen TCGA-G2-AA3D-01A (aliquot TCGA-G2-AA3D-01A-11D-A391-08) from TCGA case TCGA-G2-AA3D, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 60.8 years (22,205 days).
Specimen TCGA-G2-AA3D-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0f819290-8588-4f17-8687-b4e9a7afc70b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G2-AA3D-10A (Blood Derived Normal), aliquot TCGA-G2-AA3D-10A-01D-A394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3bacccce-8f3a-4e58-80fc-e9e1a24220ad

The open-access MAF lists 233 somatic variants for this specimen: 183 protein-altering or splice-affecting, 45 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 164, Silent 45, Nonsense Mutation 11, Intron 4, Splice Site 2, Splice Region 2, Frame Shift Ins 2, Translation Start Site 1, Frame Shift Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.402G>C p.M134I | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1114167676, CM1211213, COSV64291845, COSV64293372, COSV64295066; ClinVar: likely pathogenic; called by muse, mutect2
- TP53 | c.375G>T p.T125= | Splice Region (SNP) | VAF 25/42 reads (60%) | catalogued as rs55863639, CS004351, CS011573, CS971913, COSV52665709, COSV52718605, COSV52726641, COSV53120615; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- ABCD1 | c.731C>T p.S244L | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.7); PolyPhen benign (0.099); catalogued as rs1557052505, COSV54384796; called by muse, mutect2
- ABHD11 | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.02); catalogued as COSV56105750; called by muse, mutect2
- ADAD1 | c.363T>A p.G121= | Splice Region (SNP) | VAF 13/79 reads (16%) | catalogued as COSV56643603, COSV56647716; called by muse, varscan2
- ADAMTS6 | c.2800G>A p.E934K | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV58683056; called by muse, mutect2
- AFF2 | c.3803G>C p.R1268T | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.551); catalogued as COSV53989959; called by muse, mutect2, varscan2
- AHNAK | c.10384G>C p.D3462H | Missense Mutation (SNP) | VAF 25/153 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs372298429; called by muse, mutect2, varscan2
- AHNAK2 | c.4784A>T p.Q1595L | Missense Mutation (SNP) | VAF 22/273 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.083); catalogued as rs762550888, COSV60915615; called by muse, mutect2
- AKT2 | c.543G>T p.K181N | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100251694; called by muse, mutect2
- ALKBH8 | c.332A>G p.Q111R | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.102); catalogued as COSV52835379; called by muse, mutect2, varscan2
- APBA2 | c.2040C>G p.I680M | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV68790125, COSV68791414; called by muse, mutect2, varscan2
- ARID1A | c.4087C>T p.Q1363* | Nonsense Mutation (SNP) | VAF 27/87 reads (31%) | catalogued as COSV61381868; called by muse, mutect2, varscan2
- ARL8A | c.496G>C p.E166Q | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.51); catalogued as COSV55343267; called by muse, mutect2
- ARMC6 | c.734C>T p.A245V (on ENST00000392336; = p.A220V on NM_033415.4) | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.164); catalogued as COSV54181844; called by muse, mutect2, varscan2
- ASH1L | c.7534G>C p.D2512H (on ENST00000368346 / NM_001366177.2; = p.D2507H on NM_018489.3) | Missense Mutation (SNP) | VAF 4/87 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100853482, COSV64207940; called by muse, mutect2
- AXIN2 | c.592G>C p.E198Q | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.253); catalogued as rs772550463, COSV100196970, COSV61057637, COSV61059994; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BCL2L14 | c.599C>G p.S200C | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as COSV53787591; called by muse, mutect2, varscan2
- BIRC6 | c.7826C>T p.P2609L | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.096); catalogued as COSV70199397; called by muse, mutect2
- BSN | c.8890G>A p.E2964K | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99608896; called by muse, mutect2
- BTN3A3 | c.1402G>C p.E468Q | Missense Mutation (SNP) | VAF 6/140 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55071995; called by muse, mutect2
- C8G | c.359G>A p.R120Q | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.665); catalogued as rs753450750, COSV56403041; called by muse, mutect2, varscan2
- CA5A | c.142+1G>A p.X48_splice | Splice Site (SNP) | VAF 7/150 reads (5%) | catalogued as COSV59240794; called by muse, mutect2
- CACNA1C | c.448G>T p.D150Y | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59720272; called by muse, mutect2
- CAPN7 | c.1444C>T p.H482Y | Missense Mutation (SNP) | VAF 28/127 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53777615, COSV53778242; called by muse, mutect2, varscan2
- CAPN9 | c.1800C>G p.F600L | Missense Mutation (SNP) | VAF 15/188 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as COSV55233757; called by muse, mutect2
- CCDC174 | c.929G>C p.G310A | Missense Mutation (SNP) | VAF 47/145 reads (32%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV57980942; called by muse, mutect2, varscan2
- CCDC186 | c.952G>A p.G318S | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.878); catalogued as COSV104427825, COSV65161244; called by muse, mutect2, varscan2
- CCDC66 | c.808G>C p.E270Q (on ENST00000394672 / NM_001353147.1; = p.E236Q on NM_001012506.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/126 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV58304054, COSV58310640; called by muse, mutect2
- CCNB3 | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.537); catalogued as COSV52073908; called by muse, mutect2, varscan2
- CD72 | c.752C>G p.S251* | Nonsense Mutation (SNP) | VAF 7/151 reads (5%) | catalogued as COSV52411963; called by muse, mutect2
- CDRT4 | c.133G>C p.E45Q | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV56465357; called by muse, mutect2
- CENPP | c.848G>C p.C283S | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV55333884; called by muse, mutect2
- CFAP58 | c.673C>G p.L225V | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.199); catalogued as COSV57212182; called by muse, mutect2
- CHD8 | c.3028G>C p.G1010R (on ENST00000646647 / NM_001170629.2; = p.G731R on NM_020920.4) | Missense Mutation (SNP) | VAF 7/149 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67870594; called by muse, mutect2
- CKAP4 | c.1625C>T p.S542L | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV65172433; called by muse, mutect2
- CPNE8 | c.125C>G p.S42C | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV58841563, COSV58843424; called by muse, mutect2
- CRB1 | c.3682A>T p.T1228S | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV66330482; called by muse, mutect2, varscan2
- CTRC | c.564G>C p.R188S | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT tolerated (0.71); PolyPhen benign (0.042); catalogued as COSV65621487; called by muse, mutect2
- CUBN | c.30G>C p.W10C | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV64701489; called by muse, mutect2, varscan2
- CYP2A7 | c.84G>C p.K28N | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.011); catalogued as COSV52500816; called by muse, mutect2, varscan2
- DDX17 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT tolerated (0.38); PolyPhen benign (0.087); catalogued as COSV53252598; called by muse, mutect2
- DDX20 | c.963-1G>C p.X321_splice | Splice Site (SNP) | VAF 14/79 reads (18%) | catalogued as COSV63831086; called by muse, mutect2, varscan2
- DEPDC1 | c.562G>C p.E188Q | Missense Mutation (SNP) | VAF 6/133 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.401); catalogued as COSV63958292; called by muse, mutect2
- DHX15 | c.634A>T p.M212L | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV61026948; called by muse, mutect2, varscan2
- DIDO1 | c.5530G>C p.E1844Q | Missense Mutation (SNP) | VAF 8/121 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.203); catalogued as COSV56622580; called by muse, mutect2
- DNAH11 | c.326C>T p.S109L | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV60956137; called by muse, mutect2, varscan2
- DNAH3 | c.3747G>C p.Q1249H | Missense Mutation (SNP) | VAF 40/180 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV54522271; called by muse, varscan2
- DNAJC6 | c.2380C>G p.H794D | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.082); catalogued as rs1397362683, COSV54775100; called by muse, mutect2, varscan2
- DPF2 | c.763G>C p.E255Q | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.102); catalogued as COSV52889359; called by muse, mutect2, varscan2
- DSCAM | c.2947G>C p.A983P | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV68026911; called by muse, varscan2
- ECI2 | c.256G>C p.D86H (on ENST00000380118 / NM_206836.3; = p.D56H on NM_006117.2) | Missense Mutation (SNP) | VAF 11/118 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV60986571; called by muse, mutect2
- ECM1 | c.1247G>C p.R416P | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.783); catalogued as COSV60873025; called by muse, mutect2, varscan2
- ECM1 | c.1543G>A p.E515K | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated (0.63); PolyPhen benign (0.087); catalogued as COSV60873034; called by muse, mutect2, varscan2
- ECM2 | c.756G>C p.Q252H | Missense Mutation (SNP) | VAF 16/294 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.365); catalogued as COSV60740584; called by muse, mutect2
- EDNRB | c.289C>A p.L97M (on ENST00000377211 / NM_001201397.1; = p.L7M on NM_000115.5) | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.372); catalogued as rs1239813325, COSV57522794; called by muse, mutect2, varscan2
- EFL1 | c.2188G>A p.E730K | Missense Mutation (SNP) | VAF 10/131 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.164); catalogued as rs1321632769, COSV51605651; called by muse, mutect2
- EIF4G2 | c.722G>C p.R241T | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.223); catalogued as COSV60597118; called by muse, mutect2, varscan2
- ERICH6 | c.1108G>C p.D370H | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.526); catalogued as COSV55800500; called by muse, mutect2
- ESF1 | c.103G>A p.D35N | Missense Mutation (SNP) | VAF 6/91 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV52521026; called by muse, mutect2
- EVA1C | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs1477197184, COSV55822819; called by muse, mutect2, varscan2
- FAM78B | c.544G>C p.E182Q | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as COSV57977294; called by muse, mutect2
- FBXO40 | c.1837G>C p.E613Q | Missense Mutation (SNP) | VAF 4/78 reads (5%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.847); catalogued as COSV100573215; called by muse, mutect2
- FERD3L | c.49G>A p.V17I | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.439); catalogued as COSV51761636; called by muse, mutect2, varscan2
- GBF1 | c.1534C>G p.P512A (on ENST00000369983 / NM_001377137.1; = p.P511A on NM_004193.3) | Missense Mutation (SNP) | VAF 19/144 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.129); catalogued as COSV64145086; called by muse, mutect2, varscan2
- GLUD2 | c.1362G>C p.L454F | Missense Mutation (SNP) | VAF 4/98 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100046906; called by muse, mutect2
- GLUD2 | c.1462G>T p.V488L | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV60151979; called by muse, mutect2
- GLYR1 | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as COSV58927137; called by muse, mutect2
- GOLGA4 | c.322G>C p.D108H | Missense Mutation (SNP) | VAF 7/126 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62710763; called by muse, mutect2
- GON4L | c.5592G>C p.K1864N | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55193796; called by muse, mutect2, varscan2
- GPD1 | c.137G>A p.G46E | Missense Mutation (SNP) | VAF 7/104 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0.014); catalogued as rs893917215, COSV56548064; called by muse, mutect2
- GPR18 | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 5/99 reads (5%) | SIFT tolerated (0.45); PolyPhen benign (0.011); catalogued as COSV61621230; called by muse, mutect2
- GSPT1 | c.1489G>C p.E497Q (on ENST00000420576 / NM_001130007.2; = p.E635Q on NM_002094.4) | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.28); catalogued as COSV70452663; called by muse, mutect2
- GSTM2 | c.579T>A p.N193K | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs983113420, COSV99859689; called by muse, mutect2, varscan2
- GTSE1 | c.1366C>A p.L456I | Missense Mutation (SNP) | VAF 16/232 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.925); catalogued as COSV71889078, COSV71889155; called by muse, mutect2
- H2AX | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 6/151 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99598061, COSV99598297; called by muse, mutect2
- H3C2 | c.118C>A p.H40N | Missense Mutation (SNP) | VAF 14/208 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.545); catalogued as COSV52518813, COSV52519836; called by muse, mutect2
- HEG1 | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.017); catalogued as COSV100230645; called by muse, mutect2
- HEXIM1 | c.816G>C p.E272D | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.606); catalogued as COSV60177086; called by muse, mutect2, varscan2
- HIRIP3 | c.1465G>A p.E489K | Missense Mutation (SNP) | VAF 6/135 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54229970; called by muse, mutect2
- HPS1 | c.1514A>G p.Q505R | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV57267908; called by muse, mutect2, varscan2
- HSF2 | c.55G>C p.E19Q | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.578); catalogued as COSV63773919; called by muse, mutect2
- HSP90AB1 | c.1604C>T p.S535L | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.981); catalogued as COSV62334578, COSV62335968; called by muse, mutect2, varscan2
- HSPA13 | c.923C>T p.S308L | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV53465211; called by muse, mutect2, varscan2
- HSPB1 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.458); catalogued as rs898362811, COSV50349209; called by muse, mutect2, varscan2
- HYAL2 | c.1351G>A p.E451K | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.91); PolyPhen benign (0.001); catalogued as rs373307469, COSV63305883; called by muse, mutect2
- IGSF10 | c.2781G>A p.M927I | Missense Mutation (SNP) | VAF 8/244 reads (3%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV56785384, COSV99177119; called by muse, mutect2
- ITIH1 | c.2343G>C p.K781N | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.776); catalogued as COSV56255100; called by muse, mutect2
- JCAD | c.230G>A p.R77K | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.124); catalogued as COSV100948445; called by muse, mutect2
- KCNH3 | c.139G>C p.D47H | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57790840, COSV57791927; called by muse, mutect2, varscan2
- KDM6A | c.1082T>C p.L361P | Missense Mutation (SNP) | VAF 25/33 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65040297; called by muse, mutect2, varscan2
- KIAA2013 | c.1830C>G p.F610L | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.84); catalogued as COSV100927131; called by muse, mutect2
- KLHDC10 | c.560G>A p.C187Y | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.915); catalogued as COSV59051754; called by muse, mutect2, varscan2
- KLHDC7A | c.71C>G p.S24* | Nonsense Mutation (SNP) | VAF 3/42 reads (7%) | catalogued as COSV101272805; called by muse, mutect2
- KRT5 | c.807G>C p.E269D | Missense Mutation (SNP) | VAF 11/176 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV104383479, COSV52860729; called by muse, mutect2
- LIN54 | c.1335G>C p.Q445H | Missense Mutation (SNP) | VAF 4/76 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.979); catalogued as COSV100464692; called by muse, mutect2
- LPIN3 | c.1051C>G p.L351V | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.112); catalogued as COSV64718435; called by muse, mutect2, varscan2
- LYST | c.497C>G p.S166* | Nonsense Mutation (SNP) | VAF 5/141 reads (4%) | catalogued as COSV101089786; called by muse, mutect2
- MAP3K4 | c.298C>G p.Q100E | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.081); catalogued as COSV100815490; called by muse, mutect2
- MAST1 | c.1974G>C p.Q658H | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.779); catalogued as COSV52246956; called by muse, mutect2
- MDN1 | c.16720G>A p.A5574T | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.37); catalogued as rs774441685, COSV65521738; called by muse, mutect2, varscan2
- MED27 | c.508G>A p.D170N | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV99406702; called by muse, mutect2
- MMP10 | c.896G>C p.S299T | Missense Mutation (SNP) | VAF 5/103 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.101); catalogued as COSV54246318; called by muse, mutect2
- MTIF2 | c.619G>C p.A207P | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.983); catalogued as COSV55051546; called by muse, mutect2, varscan2
- MYBPH | c.1295C>G p.S432C | Missense Mutation (SNP) | VAF 9/122 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.199); catalogued as COSV55142545, COSV55142565; called by muse, mutect2
- MYH11 | c.827G>A p.R276K | Missense Mutation (SNP) | VAF 25/187 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55553628; called by muse, mutect2, varscan2
- MYO3B | c.3246G>C p.R1082S | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as COSV58703481, COSV58704627; called by muse, mutect2, varscan2
- N4BP2 | c.5064G>C p.Q1688H | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.412); catalogued as COSV54702009; called by muse, mutect2
- NCKAP5 | c.1756G>A p.E586K | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV58444543; called by muse, mutect2
- NCOA3 | c.1985C>G p.S662C | Missense Mutation (SNP) | VAF 31/149 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59068688; called by muse, mutect2, varscan2
- NF1 | c.7288G>C p.E2430Q (on ENST00000358273 / NM_001042492.3; = p.E2409Q on NM_000267.3) | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.406); catalogued as COSV62203669, COSV62225034; called by muse, mutect2
- NIBAN1 | c.547G>A p.D183N | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.463); catalogued as COSV100836516, COSV62284827; called by muse, mutect2, varscan2
- NPR2 | c.2794C>T p.R932C | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.3); catalogued as rs760285654, COSV52413867, COSV52414215; called by muse, mutect2, varscan2
- NUP54 | c.1054G>C p.D352H | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as COSV53575655; called by muse, mutect2, varscan2
- OAF | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.859); catalogued as rs1289709935, COSV100202951; called by muse, mutect2
- OAS2 | c.105C>G p.D35E | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.47); PolyPhen benign (0.364); catalogued as COSV60802559; called by muse, mutect2, varscan2
- OR5H1 | c.484T>G p.F162V | Missense Mutation (SNP) | VAF 43/114 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.292); catalogued as COSV63402391; called by muse, mutect2, varscan2
- P2RY14 | c.401C>A p.S134* | Nonsense Mutation (SNP) | VAF 5/67 reads (7%) | catalogued as COSV99853679; called by muse, mutect2
- PBXIP1 | c.560C>T p.A187V | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as rs755202574, COSV63777213; called by muse, mutect2, varscan2
- PDLIM5 | c.1010G>C p.R337T | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0.101); catalogued as rs1451037679, COSV58747830; called by muse, mutect2, varscan2
- PRAMEF19 | c.1146C>G p.F382L | Missense Mutation (SNP) | VAF 19/413 reads (5%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.536); catalogued as rs752653146, COSV101069152; called by muse, mutect2
- PRKAA1 | c.407C>G p.S136C | Missense Mutation (SNP) | VAF 6/137 reads (4%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV57184055, COSV57184069; called by muse, mutect2
- PSEN1 | c.395C>G p.S132* | Nonsense Mutation (SNP) | VAF 5/116 reads (4%) | catalogued as COSV56197915, COSV99997941; called by muse, mutect2
- PSG4 | c.1241C>G p.S414C | Missense Mutation (SNP) | VAF 30/239 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.765); catalogued as COSV54935804; called by muse, mutect2, varscan2
- PTPN6 | c.921C>G p.I307M | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV59684546; called by muse, mutect2
- PUM1 | c.127G>T p.G43W | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.591); catalogued as COSV57085601; called by muse, mutect2, varscan2
- RBFOX2 | c.907G>C p.D303H (on ENST00000438146 / NM_001349995.2; = p.D233H on NM_014309.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/99 reads (5%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.179); catalogued as COSV53264637; called by muse, mutect2
- RBM26 | c.884G>C p.R295T | Missense Mutation (SNP) | VAF 7/124 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.443); catalogued as COSV57394596; called by muse, mutect2
- RCN2 | c.400G>C p.D134H | Missense Mutation (SNP) | VAF 5/92 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as COSV58031654; called by muse, mutect2
- RICTOR | c.523G>C p.D175H | Missense Mutation (SNP) | VAF 5/83 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV57122146; called by muse, mutect2
- RIN3 | c.2085C>G p.I695M | Missense Mutation (SNP) | VAF 82/239 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV53648949; called by muse, mutect2, varscan2
- RIOK2 | c.1422G>C p.M474I | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1378245928, COSV99300054; called by muse, mutect2
- ROR2 | c.2018C>G p.S673* | Nonsense Mutation (SNP) | VAF 6/33 reads (18%) | catalogued as COSV65220398; called by muse, mutect2, varscan2
- RSPH1 | c.235C>G p.Q79E | Missense Mutation (SNP) | VAF 6/127 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV52318854; called by muse, mutect2
- SEMA3A | c.1288C>G p.Q430E | Missense Mutation (SNP) | VAF 9/116 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.24); catalogued as COSV54870954, COSV54873880; called by muse, mutect2
- SETBP1 | c.1108G>C p.E370Q | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.189); catalogued as COSV56314614, COSV56322238; called by muse, mutect2
- SF1 | c.469A>T p.I157F | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1475261186, COSV57113865; called by muse, varscan2
- SF1 | c.460G>A p.G154R | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1406613872, COSV57112550, COSV57113891, COSV57115514; called by muse, varscan2
- SFTPC | c.50C>T p.S17F | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV59345552; called by muse, mutect2, varscan2
- SHOC1 | c.818G>C p.C273S | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as COSV59501325; called by muse, mutect2
- SIGLEC9 | c.967C>T p.Q323* | Nonsense Mutation (SNP) | VAF 5/28 reads (18%) | catalogued as COSV99142726; called by muse, mutect2, varscan2
- SIPA1L3 | c.931G>A p.E311K | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.049); catalogued as rs995224347, COSV55916572; called by muse, mutect2
- SLC12A5 | c.1441G>T p.E481* (on ENST00000454036 / NM_001134771.2; = p.E458* on NM_020708.5) | Nonsense Mutation (SNP) | VAF 7/162 reads (4%) | catalogued as COSV54795619, COSV99716321; called by muse, mutect2
- SLC17A4 | c.1048C>G p.L350V | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT tolerated (0.49); PolyPhen benign (0.105); catalogued as COSV64956248; called by muse, mutect2
- SLC4A7 | c.1804G>A p.D602N | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55397562; called by muse, mutect2
- SLIT2 | c.3235G>A p.D1079N | Missense Mutation (SNP) | VAF 14/143 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.435); catalogued as rs756121317, COSV56572944; called by muse, mutect2
- SPEG | c.9496C>A p.P3166T | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.883); catalogued as COSV56669210; called by muse, mutect2, varscan2
- SSX1 | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as COSV100976397; called by muse, mutect2
- ST7L | c.730G>A p.E244K | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as COSV58308220; called by muse, mutect2, varscan2
- STAG2 | c.1777C>T p.Q593* | Nonsense Mutation (SNP) | VAF 10/22 reads (45%) | catalogued as COSV54356717, COSV54365939, COSV54376336; called by muse, mutect2, varscan2
- SYNE2 | c.10057G>C p.E3353Q | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.15); PolyPhen benign (0.113); catalogued as COSV59951334; called by muse, mutect2, varscan2
- TAF9 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 4/48 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.537); catalogued as COSV99472742; called by muse, mutect2
- TATDN2 | c.1696C>A p.H566N | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55051952; called by muse, mutect2
- TLK1 | c.1082C>G p.S361C | Missense Mutation (SNP) | VAF 5/86 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.401); catalogued as COSV62630381; called by muse, mutect2
- TMCC2 | c.337G>A p.G113S | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.098); catalogued as COSV58003365; called by muse, mutect2, varscan2
- TMEM130 | c.1286C>G p.S429C (on ENST00000416379 / NM_001134450.2; = p.S417C on NM_152913.3) | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.799); catalogued as COSV59559249; called by muse, mutect2, varscan2
- TNXB | c.8962G>C p.E2988Q (on ENST00000647633; = p.E2741Q on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100926423, COSV64485858; called by muse, mutect2, varscan2
- TP53I13 | c.482G>C p.R161T | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV56195351; called by muse, mutect2
- TRPC4 | c.620C>T p.S207F | Missense Mutation (SNP) | VAF 6/85 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs867675681, COSV59000298; called by muse, mutect2
- TRPV3 | c.1742A>G p.K581R | Missense Mutation (SNP) | VAF 20/149 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.833); catalogued as COSV56791567; called by muse, mutect2, varscan2
- TTC21B | c.1864G>C p.E622Q | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54630689, COSV54631675; called by muse, mutect2, varscan2
- TXNDC16 | c.486C>G p.F162L | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT tolerated (0.33); PolyPhen benign (0.01); catalogued as COSV55983845; called by muse, mutect2, varscan2
- UBL4A | c.265G>A p.D89N | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT tolerated (0.35); PolyPhen benign (0.054); catalogued as rs782283486, COSV54836217; called by muse, mutect2
- UBR5 | c.8252C>T p.S2751L | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV55287459; called by muse, mutect2, varscan2
- USP34 | c.7744G>A p.E2582K | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.931); catalogued as COSV68401430; called by muse, mutect2, varscan2
- USP47 | c.3631G>T p.E1211* (on ENST00000399455 / NM_001372095.1; = p.E1123* on NM_017944.4 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 11/62 reads (18%) | catalogued as rs1188386392, COSV100359713; called by muse, mutect2, varscan2
- VCPIP1 | c.554C>G p.S185C | Missense Mutation (SNP) | VAF 8/202 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV60047360; called by muse, mutect2
- WIF1 | c.449T>C p.F150S | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1239951601, COSV54131956; called by muse, mutect2, varscan2
- XIRP2 | c.7141G>C p.E2381Q (on ENST00000628543; = p.E2556Q on NM_152381.6) | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.131); catalogued as COSV54701233, COSV54707403; called by muse, mutect2, varscan2
- YIPF3 | c.142G>C p.E48Q | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.992); catalogued as COSV58304359; called by muse, mutect2
- YTHDC1 | c.1546C>G p.Q516E (on ENST00000344157 / NM_001031732.4; = p.Q498E on NM_133370.4) | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as COSV100704766; called by muse, mutect2
- YTHDF2 | c.1347G>A p.M449I | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.44); PolyPhen benign (0.017); catalogued as COSV65723273; called by muse, mutect2, varscan2
- ZFAT | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64738769; called by muse, mutect2, varscan2
- ZFYVE26 | c.6682G>T p.D2228Y | Missense Mutation (SNP) | VAF 12/387 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61328476; called by muse, mutect2
- ZNF267 | c.1021C>G p.Q341E | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1177293276, COSV56253076; called by muse, mutect2, varscan2
- ZNF569 | c.1975G>C p.E659Q | Missense Mutation (SNP) | VAF 5/108 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.97); catalogued as COSV57595519; called by muse, mutect2
- ZNF594 | c.2217G>C p.E739D | Missense Mutation (SNP) | VAF 7/127 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.024); catalogued as COSV68385304; called by muse, mutect2
- ZNF594 | c.757G>C p.D253H | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (0.46); PolyPhen benign (0.05); catalogued as COSV68384745; called by muse, mutect2
- ZNHIT1 | c.235C>T p.R79C | Missense Mutation (SNP) | VAF 7/145 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1364666223, COSV59313115; called by muse, mutect2
- DIDO1 | c.2613dup p.Q872Tfs*8 | Frame Shift Ins (INS) | VAF 25/207 reads (12%) | called by mutect2, pindel, varscan2
- E2F8 | c.799del p.R267Gfs*2 | Frame Shift Del (DEL) | VAF 43/102 reads (42%) | called by mutect2, pindel, varscan2
- GLE1 | c.1622dup p.M542Nfs*83 | Frame Shift Ins (INS) | VAF 12/110 reads (11%) | called by mutect2, pindel, varscan2
- ZNF85 | c.1232C>T p.S411L | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.721); called by muse, mutect2
- ABR | c.564C>G p.V188= (on ENST00000302538 / NM_021962.5; = p.V151= on NM_001092.5) | Silent (SNP) | VAF 32/82 reads (39%) | catalogued as rs1486359797, COSV52145756; called by muse, mutect2, varscan2
- ACSL4 | c.675C>T p.I225= (on ENST00000340800 / NM_022977.2; = p.I184= on NM_004458.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 4/66 reads (6%) | catalogued as COSV100538283, COSV100538680; called by muse, mutect2
- AHCTF1 | c.3015G>C p.L1005= (on ENST00000366508; = p.L979= on NM_015446.5) | Silent (SNP) | VAF 10/76 reads (13%) | catalogued as COSV100403177, COSV58250323; called by muse, mutect2, varscan2
- BICRAL | c.1902G>C p.L634= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as COSV58405670; called by muse, mutect2, varscan2
- C16orf70 | c.1248G>A p.L416= | Silent (SNP) | VAF 9/100 reads (9%) | catalogued as COSV54627286; called by muse, mutect2
- CCDC88A | c.3552G>A p.L1184= | Silent (SNP) | VAF 6/136 reads (4%) | catalogued as COSV55061810; called by muse, mutect2
- CSGALNACT1 | c.1119G>C p.L373= | Silent (SNP) | VAF 20/53 reads (38%) | catalogued as COSV59977716, COSV59979654; called by muse, mutect2, varscan2
- FGFR2 | c.981C>G p.L327= | Silent (SNP) | VAF 15/66 reads (23%) | catalogued as COSV60647207, COSV60655465; called by muse, mutect2, varscan2
- GADD45A | c.228C>G p.T76= | Silent (SNP) | VAF 17/67 reads (25%) | catalogued as COSV63974821; called by muse, mutect2, varscan2
- GLYCTK | c.999G>A p.L333= | Silent (SNP) | VAF 5/69 reads (7%) | catalogued as COSV99980834; called by muse, mutect2
- GNAO1 | c.198G>A p.V66= | Silent (SNP) | VAF 36/66 reads (55%) | catalogued as COSV52614091, COSV52621620; called by muse, mutect2, varscan2
- GRM3 | c.2493G>A p.Q831= | Silent (SNP) | VAF 4/55 reads (7%) | catalogued as COSV100862651; called by muse, mutect2
- GRM6 | c.2532C>G p.L844= | Silent (SNP) | VAF 12/111 reads (11%) | catalogued as rs137914807; called by muse, mutect2, varscan2
- HAUS5 | c.1419G>T p.L473= | Silent (SNP) | VAF 25/185 reads (14%) | catalogued as COSV52547970; called by muse, mutect2, varscan2
- INMT | c.561C>G p.L187= | Silent (SNP) | VAF 6/106 reads (6%) | catalogued as COSV50000013; called by muse, mutect2
- KBTBD3 | c.852C>G p.L284= | Silent (SNP) | VAF 8/90 reads (9%) | catalogued as rs1478403903, COSV73241424; called by muse, mutect2
- KDM4A | c.2856C>G p.L952= | Silent (SNP) | VAF 8/126 reads (6%) | catalogued as COSV53514172; called by muse, mutect2
- LRRC49 | c.822C>T p.I274= | Silent (SNP) | VAF 9/145 reads (6%) | catalogued as COSV53010903; called by muse, mutect2
- MFSD1 | c.720G>A p.E240= | Silent (SNP) | VAF 23/64 reads (36%) | catalogued as rs1173936468, COSV51840458, COSV51840791; called by muse, mutect2, varscan2
- NEGR1 | c.216G>A p.L72= | Silent (SNP) | VAF 7/75 reads (9%) | catalogued as COSV60845410; called by muse, mutect2
- NEXMIF | c.792T>C p.F264= | Silent (SNP) | VAF 43/64 reads (67%) | catalogued as COSV50031845; called by muse, mutect2, varscan2
- NF1 | c.7290A>G p.E2430= (on ENST00000358273 / NM_001042492.3; = p.E2409= on NM_000267.3) | Silent (SNP) | VAF 4/47 reads (9%) | catalogued as COSV62203681; called by muse, mutect2
- NLRP4 | c.2580C>A p.L860= | Silent (SNP) | VAF 24/171 reads (14%) | catalogued as COSV56713900; called by muse, mutect2, varscan2
- NOP56 | c.1068C>T p.F356= | Silent (SNP) | VAF 8/80 reads (10%) | catalogued as COSV61390033; called by muse, mutect2, varscan2
- NPAT | c.3861C>T p.I1287= | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as COSV53718116; called by muse, mutect2, varscan2
- OR2H1 | c.540A>G p.P180= | Silent (SNP) | VAF 10/204 reads (5%) | catalogued as COSV65810684; called by muse, mutect2
- P3H2 | c.2100G>A p.L700= | Silent (SNP) | VAF 20/128 reads (16%) | catalogued as COSV60021695; called by muse, mutect2, varscan2
- PCDHA1 | c.834C>G p.V278= | Silent (SNP) | VAF 13/128 reads (10%) | catalogued as COSV65374446; called by muse, mutect2
- PCDHB3 | c.636C>T p.L212= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as COSV50574684; called by muse, mutect2, varscan2
- PCDHGA1 | c.1683G>A p.E561= | Silent (SNP) | VAF 7/192 reads (4%) | catalogued as COSV65294714, COSV65296345; called by muse, mutect2
- PSENEN | c.195C>G p.L65= | Silent (SNP) | VAF 14/118 reads (12%) | catalogued as COSV53074773; called by muse, mutect2, varscan2
- RNF145 | c.93C>T p.V31= (on ENST00000424310 / NM_001199383.2; = p.V59= on NM_144726.2) | Silent (SNP) | VAF 12/98 reads (12%) | catalogued as COSV50866515; called by muse, mutect2, varscan2
- SCML4 | c.351G>A p.Q117= | Silent (SNP) | VAF 11/85 reads (13%) | catalogued as COSV64633823, COSV64635658; called by muse, mutect2, varscan2
- SIGLEC6 | c.1134C>T p.A378= | Silent (SNP) | VAF 22/114 reads (19%) | catalogued as rs762967772, COSV58434325; called by muse, mutect2, varscan2
- SP1 | c.2323C>T p.L775= (on ENST00000327443 / NM_138473.3; = p.L768= on NM_003109.1) | Silent (SNP) | VAF 6/74 reads (8%) | catalogued as COSV59402937; called by muse, mutect2
- SYNJ1 | c.477G>C p.R159= | Silent (SNP) | VAF 4/51 reads (8%) | catalogued as COSV100449421; called by muse, mutect2
- TRIM46 | c.897G>A p.V299= | Silent (SNP) | VAF 9/74 reads (12%) | catalogued as COSV99825998; called by muse, mutect2
- TRIM60 | c.1219C>T p.L407= | Silent (SNP) | VAF 9/147 reads (6%) | catalogued as COSV61970549; called by muse, mutect2
- TSPAN33 | c.204G>T p.L68= | Silent (SNP) | VAF 3/32 reads (9%) | catalogued as COSV99179747; called by muse, mutect2
- TTN | c.15453C>T p.C5151= (on ENST00000591111; = p.C4224= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as COSV60070568; called by muse, mutect2
- UMODL1 | c.921G>A p.L307= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as COSV68555949; called by muse, mutect2
- ZBTB40 | c.1083G>C p.L361= | Silent (SNP) | VAF 7/80 reads (9%) | catalogued as COSV65145345; called by muse, mutect2
- ZFAT | c.1053G>A p.K351= | Silent (SNP) | VAF 9/69 reads (13%) | catalogued as COSV64738757; called by muse, mutect2, varscan2
- ZNF76 | c.813C>T p.I271= | Silent (SNP) | VAF 5/75 reads (7%) | catalogued as COSV57591480; called by muse, mutect2
- ZYG11B | c.429G>A p.L143= | Silent (SNP) | VAF 5/82 reads (6%) | catalogued as COSV99597527; called by muse, mutect2
- FBXW7 | c.502-2489G>A | Intron (SNP) | VAF 9/34 reads (26%) | catalogued as rs758387799, COSV55916845, COSV55937200; called by muse, mutect2, varscan2
- NOP56 | c.1010+108C>T | Intron (SNP) | VAF 4/32 reads (13%) | catalogued as rs756884147, COSV100250185; called by mutect2, varscan2
- PLOD1 | c.741+163C>T | Intron (SNP) | VAF 34/101 reads (34%) | catalogued as COSV52144221; called by muse, mutect2, varscan2
- RTBDN | chr19:12834805 C>G | 5'Flank (SNP) | VAF 25/95 reads (26%) | catalogued as COSV52246941; called by muse, mutect2, varscan2
- TPH2 | c.609-10889C>T | Intron (SNP) | VAF 6/85 reads (7%) | catalogued as COSV100421842; called by muse, mutect2
